Gene-level copy-number profile of tumor specimen TCGA-HS-A5N8-01A from TCGA case TCGA-HS-A5N8, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 69.9 years (25,549 days).
Specimen TCGA-HS-A5N8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.5ee66c48-47f1-4733-8a41-a57aeadc6d07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HS-A5N8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e2b3b354-c26a-4070-a6cc-c1b9ef70cab1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 446; copy number 2: 32,691; copy number 3: 13,617; copy number 4: 11,453; copy number 5: 1,063; copy number 6: 487; copy number 8: 4; copy number 22: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HS-A5N8-01A-11D-A26F-01): tumor purity 0.74, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–116,932,238, 3 genes: MIR4447, AC069504.1, LINC00901.
- chr4:181,237,358–181,265,145, 2 genes (within-gene range 0–1): AC019235.1, LINC02500.
- chr8:135,742,343–135,742,495, 1 gene: RNU1-35P.
- chr13:32,303,699–33,066,143, 15 genes (within-gene range 0–2): ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,588 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:28,683,976–33,418,564, 80 genes, copy number 6 (broad region; genes not listed).
- chr5:56,192,530–56,976,224, 20 genes, copy number 6: C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1, AC008940.1, MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1.
- chr8:126,325,454–128,220,803, 34 genes, copy number 22: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr11:85,683,848–86,345,943, 17 genes, copy number 6 (within-gene range 4–6): CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P.
- chr13:21,260,015–26,025,851, 102 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr17:45,506,741–76,619,128, 907 genes, copy number 5 (broad region; genes not listed).
- chr17:79,598,032–79,742,219, 4 genes, copy number 8: AC233701.1, MIR4739, LINC02078, ENPP7.
- chr19:28,294,093–30,957,192, 54 genes, copy number 5: AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr19:55,488,404–55,932,336, 27 genes, copy number 6 (within-gene range 4–6): SSC5D, SBK2, SBK3, ZNF579, FIZ1, ZNF524, ZNF865, AC008735.4, ZNF784, ZNF580, ZNF581, CCDC106, U2AF2, AC008735.2, AC008735.1, EPN1, AC010525.1, AC010525.2, AC008749.1, NLRP9, RN7SKP109, RFPL4A, RFPL4AL1, RFPL4AP1, NLRP11, NLRP4, NLRP13.
- chr22:30,285,238–40,335,808, 343 genes, copy number 6 (within-gene range 5–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 446. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
